Somatic mutation profile of tumor specimen 0DXLTP from CCDI case PBCRPA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 11.1 years (4,045 days).
Specimen 0DXLTP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f1146cd-5890-4036-bc9e-874b6cb606ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXLT7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2890b80e-cfa2-4369-906e-b28da4958d65

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Nonsense Mutation 2, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZFX | c.1948C>T p.R650* | Nonsense Mutation (SNP) | VAF 13/292 reads (4%) | catalogued as COSV58446653; called by muse, mutect2
- ADGRG2 | c.1391C>T p.T464I (on ENST00000379869 / NM_001079858.3; = p.T461I on NM_005756.4) | Missense Mutation (SNP) | VAF 51/225 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- CCT6B | c.1483T>G p.W495G | Missense Mutation (SNP) | VAF 105/384 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- IRX5 | c.659G>C p.G220A | Missense Mutation (SNP) | VAF 173/330 reads (52%) | SIFT tolerated (0.8); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MFSD8 | c.1513A>T p.R505* | Nonsense Mutation (SNP) | VAF 157/387 reads (41%) | called by muse, mutect2, varscan2
- TTN | c.26323A>T p.I8775L (on ENST00000591111; = p.I7848L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/365 reads (21%) | PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BECN2 | c.162C>T p.D54= | Silent (SNP) | VAF 94/204 reads (46%) | called by muse, mutect2, varscan2
- PLEKHG2 | c.*121C>T | 3'UTR (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- SLC27A1 | c.1206+33G>A | Intron (SNP) | VAF 122/263 reads (46%) | catalogued as rs769114721; called by muse, mutect2, varscan2
- TTN | c.82196-25T>A | Intron (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
